Somatic mutation profile of tumor specimen 0DQJIV from CCDI case PBCEPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 19.3 years (7,041 days).
Specimen 0DQJIV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2099e606-f547-4549-ad0e-21c089a7d854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQJII (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bdb8db5-6d05-4aea-8a93-a905b5d90d13

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9A | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.322); catalogued as rs1568806115, COSV100125591, COSV58764277; called by muse, mutect2
- CAPN6 | c.961G>T p.G321* | Nonsense Mutation (SNP) | VAF 34/151 reads (23%) | catalogued as COSV100136817; called by muse, mutect2, varscan2
- SGSM1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as rs376542790; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs761621106; called by muse, mutect2
- C4A | c.4123A>G p.K1375E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- DDX60L | c.4649A>T p.E1550V | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FAM47A | c.2266_2267insT p.R756Mfs*11 | Frame Shift Ins (INS) | VAF 58/181 reads (32%) | called by mutect2, pindel, varscan2
- RP1 | c.3144G>T p.E1048D | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.054); called by muse, mutect2
- SLC22A8 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 83/189 reads (44%) | called by muse, mutect2, varscan2
- ACAN | c.5268C>T p.S1756= | Silent (SNP) | VAF 85/234 reads (36%) | catalogued as rs775729780, COSV61359916; called by muse, mutect2, varscan2
- CD163L1 | c.4143G>A p.T1381= | Silent (SNP) | VAF 87/259 reads (34%) | catalogued as rs144374967; called by muse, mutect2, varscan2
- GZMH | c.588C>T p.T196= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as rs751202637, COSV99361935; called by muse, mutect2, varscan2
- ZNF597 | c.309G>A p.A103= | Silent (SNP) | VAF 102/243 reads (42%) | catalogued as rs372249389, COSV57084691; called by muse, mutect2, varscan2
